Gene-level copy-number profile of tumor specimen HCM-SANG-1311-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-1311-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1311-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7389dc17-3197-4019-97d7-413d6940cc8f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1311-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/ca1f0608-8f26-4d40-894d-2eff4144be8e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 554; copy number 1: 12,546; copy number 2: 40,154; copy number 3: 3,265; copy number 4: 2,330; copy number 5: 13; copy number 6: 49.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,768,977–8,226,614, 31 genes: FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1.
- chr22:22,711,689–22,739,187, 6 genes (within-gene range 0–1): IGLV3-21, IGLVI-20, IGLV3-19, AC244250.3, IGLV2-18, IGLV3-17.
- chr22:22,755,554–22,762,516, 3 genes (within-gene range 0–1): IGLV3-15, IGLV2-14, IGLV3-13.
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–1): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 62 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,695,782–38,409,527, 35 genes, copy number 6: ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2.
- chr8:38,408,048–38,408,742, 1 gene, copy number 6: AC087623.3.
- chr8:39,902,275–40,520,158, 13 genes, copy number 6: IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1.
- chr20:25,248,085–25,298,012, 1 gene, copy number 5 (within-gene range 3–5): PYGB.
- chr20:25,284,915–25,390,835, 3 genes, copy number 5: AL121772.3, ABHD12, PPIAP2.
- chr20:51,596,514–52,204,308, 9 genes, copy number 5: ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1.

Autosomal genes at a single copy (total copy number 1): 10,202. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
